Somatic mutation profile of tumor specimen TCGA-UF-A7JO-01A (aliquot TCGA-UF-A7JO-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.3 years (28,951 days).
Specimen TCGA-UF-A7JO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8db1abc1-35fd-4271-bf36-6dbaa032c5bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JO-10A (Blood Derived Normal), aliquot TCGA-UF-A7JO-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4420008c-51b4-4b52-8e8e-edd5fdfe6b1c

The open-access MAF lists 185 somatic variants for this specimen: 133 protein-altering or splice-affecting, 47 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 47, Nonsense Mutation 8, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, 5'Flank 1, In Frame Ins 1, RNA 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 23/119 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC2A2 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs121909741, CM941278; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, varscan2
- ADAM21 | c.2051T>C p.L684S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV50791436, COSV99960361; called by mutect2, varscan2
- ADAR | c.2232C>G p.F744L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV52712755, COSV99425353; called by muse, mutect2, varscan2
- ADGRB3 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.025); catalogued as COSV100999578; called by muse, mutect2, varscan2
- AGTR1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100836906; called by muse, mutect2, varscan2
- AKAP11 | c.4900C>T p.H1634Y | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV99213386; called by muse, mutect2, varscan2
- ANKRD52 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99920971; called by muse, mutect2, varscan2
- ARHGAP29 | c.3101G>A p.R1034K | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as COSV99557447; called by muse, mutect2, varscan2
- ARID4A | c.2631G>A p.M877I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100793948; called by muse, mutect2, varscan2
- ATR | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as rs758564083, COSV100638481, COSV63386612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCO2 | c.519C>A p.A173= | Splice Region (SNP) | VAF 18/94 reads (19%) | catalogued as COSV63062792; called by muse, mutect2, varscan2
- CACNA1G | c.7126G>A p.D2376N | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.427); catalogued as COSV100661021; called by muse, mutect2, varscan2
- CARD8 | c.1468G>C p.E490Q (on ENST00000651546 / NM_001184900.3; = p.E440Q on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV100750970, COSV62872770; called by muse, mutect2
- CATSPERE | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100834855; called by muse, mutect2, varscan2
- CCDC172 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100319617; called by muse, mutect2, varscan2
- CCDC88C | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV101105010; called by muse, mutect2
- CD84 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs777494416, COSV60870954; called by muse, mutect2, varscan2
- CGN | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99641748; called by muse, mutect2, varscan2
- CLN6 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs140519790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGA3 | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV99735927; called by muse, mutect2
- COL6A3 | c.8627C>T p.P2876L | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs367635298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIS3L2 | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99805105; called by muse, mutect2, varscan2
- DNAH9 | c.8577C>A p.D2859E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.699); catalogued as COSV99069807; called by muse, mutect2
- EFTUD2 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101274506; called by muse, mutect2, varscan2
- EVPL | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs763830732, COSV56909883; called by muse, mutect2, varscan2
- EXOC3L1 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV99333351; called by muse, mutect2, varscan2
- FAM186B | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs139362702; called by muse, mutect2, varscan2
- FAM83H | c.3224C>T p.P1075L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs782190930, COSV100567652, COSV100567935; called by muse, mutect2
- FAT1 | c.11078A>G p.D3693G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV101498656; called by muse, mutect2, varscan2
- FAT1 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV101498660; called by muse, mutect2, varscan2
- FCRL4 | c.1163T>A p.V388D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs1249814889, COSV99619159; called by muse, mutect2, varscan2
- FETUB | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759546734, COSV99408828; called by muse, mutect2, varscan2
- FILIP1 | c.3419G>A p.R1140Q | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs770451999, COSV99383642, COSV99385296; called by muse, mutect2, varscan2
- FLT4 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774554521, COSV56112322, COSV99987558; called by muse, mutect2, varscan2
- GABARAPL1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99845370; called by muse, mutect2
- GABRE | c.680G>C p.W227S | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100944194; called by muse, mutect2, varscan2
- GEMIN8 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs778858984, COSV100256902; called by muse, mutect2
- GLUD1 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM004843, COSV99517852; called by muse, mutect2, varscan2
- GPX1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV69042790, COSV69043951; called by muse, mutect2, varscan2
- GRIA1 | c.2662C>A p.Q888K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.248); catalogued as COSV99597710; called by muse, mutect2, varscan2
- GRIK1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV58718851; called by muse, mutect2, varscan2
- HELZ2 | c.6338C>T p.A2113V (on ENST00000467148 / NM_001037335.2; = p.A1544V on NM_033405.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs571327252, COSV101427504; called by muse, mutect2, varscan2
- HMCN1 | c.13735C>G p.Q4579E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV99622947; called by muse, mutect2, varscan2
- HTR1D | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757946711, COSV58447419; called by muse, mutect2, varscan2
- IGHV3-11 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs782601313; called by muse, mutect2, varscan2
- INPP5A | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.389); catalogued as COSV100704056; called by muse, mutect2, varscan2
- IQSEC2 | c.3064C>T p.R1022C (on ENST00000642864 / NM_001111125.3; = p.R817C on NM_015075.2) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV64728168; called by muse, mutect2
- KBTBD3 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); catalogued as COSV101595656, COSV73241499; called by muse, mutect2, varscan2
- KIAA1143 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV56089478, COSV99941514; called by muse, mutect2
- KPNA4 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV100514929; called by muse, mutect2, varscan2
- LCN15 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100293253; called by muse, mutect2, varscan2
- LGALS2 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as rs753087956, COSV99312320; called by muse, mutect2, varscan2
- LPA | c.5009C>T p.A1670V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100305886; called by muse, mutect2, varscan2
- LRRC10 | c.291G>C p.L97F | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100825434, COSV64060085; called by muse, mutect2
- LRRC8C | c.1248G>C p.Q416H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100967916; called by muse, mutect2
- LRRTM3 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791425, COSV63665945; called by muse, mutect2, varscan2
- LSR | c.1162C>T p.R388C (on ENST00000361790; = p.R369C on NM_015925.6) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs956284991, COSV99723230; called by muse, mutect2, varscan2
- MAN1A2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100740756, COSV62979701; called by muse, mutect2
- MAP2 | c.4249G>C p.A1417P | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV99557386; called by muse, mutect2
- METTL17 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100228020, COSV59555216; called by muse, mutect2, varscan2
- METTL2B | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV52310718, COSV99299600; called by muse, mutect2, varscan2
- MFN2 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs766735605, COSV52420944, COSV99336410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC5B | c.15923C>T p.P5308L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs769440902, COSV101499971; called by muse, mutect2, varscan2
- MXI1 | c.206+2T>C p.X69_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99491212; called by muse, mutect2, varscan2
- NCAM2 | c.327G>T p.L109F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99520518; called by muse, mutect2, varscan2
- NDUFS5 | c.54G>C p.L18F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100880404; called by muse, mutect2
- NFKB1 | c.2702C>A p.A901D (on ENST00000394820 / NM_001382627.1; = p.A902D on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV99896532; called by muse, mutect2, varscan2
- NUP153 | c.4256C>A p.A1419E | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99467197; called by muse, mutect2
- OGDHL | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.196); catalogued as COSV100934164; called by muse, mutect2, varscan2
- OR2C3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs147306837, COSV63574800; called by muse, mutect2, varscan2
- OR2F2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV68832559, COSV68832730; called by muse, mutect2, varscan2
- OR7A5 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs765705586, COSV100457574; called by muse, mutect2, varscan2
- PACS2 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV100330559; called by muse, mutect2, varscan2
- PADI3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs763690862, COSV64934650; called by muse, mutect2, varscan2
- PAN2 | c.3331C>T p.R1111* (on ENST00000425394 / NM_001127460.3; = p.R1107* on NM_014871.5) | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as rs375649878; called by muse, mutect2, varscan2
- PCDHB3 | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99164105; called by muse, mutect2, varscan2
- PCDHGC3 | c.1322C>G p.T441R | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV99337360; called by muse, mutect2, varscan2
- PIK3C2G | c.192dup p.V65Cfs*16 | Frame Shift Ins (INS) | VAF 16/102 reads (16%) | catalogued as rs1565550462; called by mutect2, pindel, varscan2
- PIK3CA | c.2713T>A p.C905S | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99832817; called by muse, mutect2, varscan2
- PITPNM3 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs868086165, COSV99337814; called by muse, mutect2, varscan2
- PLS1 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs146341428; called by muse, mutect2, varscan2
- PPTC7 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV100845677; called by muse, mutect2, varscan2
- PRDM1 | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV100958495; called by muse, mutect2, varscan2
- PREX2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs750933833, COSV55778622; called by muse, mutect2, varscan2
- PTPRZ1 | c.1340G>T p.R447I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as rs760432564, COSV101099303; called by muse, mutect2, varscan2
- RASGRP1 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100171669; called by muse, mutect2, varscan2
- RNF141 | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99792747; called by muse, mutect2
- RPRD2 | c.2417G>C p.G806A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100954833; called by muse, mutect2, varscan2
- SCLT1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.277); catalogued as COSV99827458; called by muse, mutect2, varscan2
- SEC13 | c.128G>A p.R43H (on ENST00000350697 / NM_183352.3; = p.R46H on NM_030673.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs201150723, COSV61601598; called by muse, mutect2, varscan2
- SEPTIN6 | c.342-1G>A p.X114_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | catalogued as COSV59715082; called by muse, mutect2, varscan2
- SETD3 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV100074774; called by muse, mutect2
- SGPP1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99905669; called by muse, mutect2, varscan2
- SIGLEC6 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100585110; called by muse, mutect2, varscan2
- SIMC1 | c.2269C>G p.Q757E (on ENST00000443967 / NM_001308196.1; = p.Q342E on NM_198567.5) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV100230893; called by muse, mutect2
- SLC9B2 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100293652; called by muse, mutect2, varscan2
- SMC5 | c.2819A>T p.N940I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100746925; called by muse, mutect2, varscan2
- SMG6 | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99557644, COSV99558465; called by muse, mutect2, varscan2
- SPATA22 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV99279036; called by muse, mutect2, varscan2
- SPIN4 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100633292; called by muse, mutect2, varscan2
- SSX7 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993670; called by muse, mutect2
- TACC3 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1239586281, COSV57606715; called by muse, mutect2, varscan2
- TAF1 | c.1951C>A p.L651I (on ENST00000373790 / NM_138923.4; = p.L672I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113051; called by muse, mutect2
- TAF1 | c.3028C>T p.R1010C (on ENST00000373790 / NM_138923.4; = p.R1031C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52106400; called by muse, mutect2, varscan2
- TERT | c.2744G>A p.G915D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as rs202033269, COSV99715806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIPARP | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.129); catalogued as COSV99903631; called by muse, mutect2
- TMTC4 | c.1821G>A p.W607* (on ENST00000376234 / NM_001350577.2; = p.W626* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/147 reads (24%) | catalogued as rs997753336, COSV60891752; called by muse, mutect2, varscan2
- TNK2 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs777940731, COSV100360894; called by muse, varscan2
- TP53 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as rs1555526581, CM013441, COSV52748282, COSV52919256, COSV53146850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53BP2 | c.2384A>G p.N795S (on ENST00000343537 / NM_001031685.3; = p.N666S on NM_005426.2) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV100636486; called by muse, mutect2, varscan2
- TRBV24-1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs762956419; called by muse, mutect2, varscan2
- TRMT2B | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs757181399, COSV100105103; called by muse, mutect2, varscan2
- TTN | c.10141G>C p.D3381H (on ENST00000591111; = p.D3335H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | PolyPhen possibly damaging (0.673); catalogued as COSV100590625; called by muse, mutect2, varscan2
- UBQLN2 | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100592605; called by muse, mutect2, varscan2
- UNC50 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1455593184, COSV60830920; called by muse, mutect2
- USP26 | c.2562G>T p.W854C | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100896499; called by muse, mutect2, varscan2
- VPS50 | c.1262+1G>A p.X421_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100004388; called by muse, mutect2
- WDR76 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.502); catalogued as rs1303261103, COSV99776029; called by muse, mutect2, varscan2
- XDH | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65149114, COSV65149907; called by muse, mutect2, varscan2
- ZFAND5 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99428372; called by muse, mutect2, varscan2
- ZFR | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs1350079146, COSV99415235; called by muse, mutect2, varscan2
- ZNF276 | c.1549C>T p.R517* (on ENST00000443381 / NM_001113525.2; = p.R442* on NM_152287.4) | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as rs763134179, COSV57066518; called by muse, mutect2, varscan2
- ZNF510 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); catalogued as COSV99793698; called by muse, mutect2, varscan2
- ZNF595 | c.1320A>G p.I440M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs782598971, COSV100227371; called by muse, mutect2, varscan2
- CASP8 | c.151_152del p.K51Efs*19 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- FAT1 | c.8474dup p.S2826Kfs*2 | Frame Shift Ins (INS) | VAF 16/153 reads (10%) | called by mutect2, pindel
- HLA-B | c.635_636del p.H212Rfs*8 | Frame Shift Del (DEL) | VAF 58/155 reads (37%) | called by pindel, varscan2
- NEIL1 | c.1171T>C p.*391Qext*59 | Nonstop Mutation (SNP) | VAF 2/24 reads (8%) | called by muse, mutect2
- PLXNA1 | c.5389_5391dup p.S1797dup | In Frame Ins (INS) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.476G>T p.C159F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AGBL5 | c.1278C>T p.G426= | Silent (SNP) | VAF 63/283 reads (22%) | catalogued as rs1025088650, COSV59935772; called by muse, mutect2, varscan2
- BCAR3 | c.2005C>T p.L669= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV99550083; called by muse, mutect2, varscan2
- CALCA | c.126C>T p.L42= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV59027996; called by muse, mutect2, varscan2
- CCDC112 | c.411T>A p.P137= | Silent (SNP) | VAF 46/191 reads (24%) | catalogued as COSV101100341; called by muse, mutect2, varscan2
- CHN1 | c.687C>G p.L229= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99788883; called by muse, mutect2
- CHRM1 | c.1260C>G p.L420= | Silent (SNP) | VAF 54/229 reads (24%) | catalogued as rs1565264230, COSV100186045; called by muse, mutect2, varscan2
- COL6A2 | c.834G>A p.E278= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100152822; called by muse, mutect2, varscan2
- CTNNA2 | c.936C>T p.S312= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs779257738, COSV63547323, COSV63592832; called by muse, mutect2, varscan2
- CYP7B1 | c.129C>T p.P43= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as rs1471365409, COSV59589698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCTN1 | c.1300C>T p.L434= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV100720850, COSV62621648; called by muse, mutect2, varscan2
- DEF8 | c.294C>T p.D98= (on ENST00000268676 / NM_207514.3; = p.D37= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs759040124, COSV99240144; called by muse, mutect2, varscan2
- DUSP8 | c.207C>T p.L69= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100524201; called by muse, mutect2
- ERF | c.280C>T p.L94= | Silent (SNP) | VAF 34/235 reads (14%) | catalogued as rs770925496, COSV99724435; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM155A | c.657G>A p.S219= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs1361386546, COSV65549346; called by muse, mutect2, varscan2
- FFAR1 | c.507C>T p.V169= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99322727; called by muse, mutect2, varscan2
- GPR149 | c.615C>T p.L205= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV101078051; called by muse, mutect2, varscan2
- HMGCS1 | c.460C>T p.L154= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100284884; called by muse, mutect2, varscan2
- ITGA7 | c.2940A>C p.P980= (on ENST00000555728; = p.P936= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99144148; called by muse, mutect2, varscan2
- KCTD3 | c.1197G>A p.V399= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV99378732; called by muse, mutect2, varscan2
- KIF1A | c.4611G>A p.R1537= (on ENST00000320389 / NM_001379639.1; = p.R1529= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- LCK | c.153C>T p.Y51= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs950834998, COSV100287352; called by muse, mutect2, varscan2
- LMNTD2 | c.492C>T p.L164= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99529322; called by mutect2, varscan2
- LRFN2 | c.1935C>T p.S645= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs775902019, COSV57825838; called by muse, mutect2, varscan2
- LRRC71 | c.819G>A p.A273= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100503745; called by muse, mutect2, varscan2
- LTB | c.337C>T p.L113= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs1237145100, COSV101438037; called by muse, mutect2, varscan2
- MAB21L4 | c.210C>T p.F70= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs777658838, COSV100278374; called by muse, mutect2, varscan2
- MAP1A | c.1680T>C p.P560= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100287942; called by muse, mutect2, varscan2
- MED16 | c.1317G>A p.T439= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs770968682, COSV99515030; called by muse, mutect2, varscan2
- MTBP | c.1395G>A p.Q465= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV104400576, COSV59966997; called by muse, mutect2
- MUC16 | c.41667C>T p.I13889= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as COSV101109513; called by muse, mutect2, varscan2
- NETO2 | c.1509G>A p.E503= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV100292331; called by muse, mutect2, varscan2
- NLRC4 | c.2214G>T p.L738= | Silent (SNP) | VAF 40/379 reads (11%) | catalogued as COSV100707149; called by muse, mutect2, varscan2
- PAH | c.1224G>T p.R408= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100187541; called by muse, mutect2, varscan2
- PIK3C2B | c.81C>T p.A27= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs748643053, COSV100914985; called by muse, mutect2, varscan2
- PLCG1 | c.1896C>G p.L632= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99718381; called by muse, mutect2, varscan2
- PLIN4 | c.2220T>C p.T740= (on ENST00000301286; = p.T755= on NM_001367868.2) | Silent (SNP) | VAF 32/370 reads (9%) | catalogued as rs200701465; called by muse, mutect2
- PRKACA | c.201G>A p.G67= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as rs1319752020, COSV100431657, COSV58068724; called by muse, mutect2
- RING1 | c.6G>A p.T2= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1345997788, COSV100761710; called by muse, mutect2
- SFTPA1 | c.159C>T p.D53= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100956872; called by muse, varscan2
- SLC13A5 | c.183C>G p.L61= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99545614; called by muse, mutect2, varscan2
- SLITRK4 | c.192C>G p.L64= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV100567091; called by muse, mutect2, varscan2
- SQOR | c.399C>T p.D133= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs770249680, COSV99525461; called by muse, mutect2, varscan2
- STARD6 | c.662G>A p.*221= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV100323335; called by muse, mutect2, varscan2
- SV2A | c.1653C>T p.F551= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as COSV100974958; called by muse, mutect2, varscan2
- SYNGAP1 | c.96C>T p.T32= | Silent (SNP) | VAF 14/253 reads (6%) | catalogued as COSV99537721; called by muse, mutect2
- UVRAG | c.852C>G p.L284= | Silent (SNP) | VAF 46/207 reads (22%) | catalogued as COSV100638013; called by muse, mutect2, varscan2
- VSIG4 | c.525T>C p.Y175= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV101038014; called by muse, mutect2
- ANKRD13C | chr1:70355006 G>A | 5'Flank (SNP) | VAF 12/43 reads (28%) | catalogued as rs1372475044, COSV99256067; called by muse, mutect2, varscan2
- C9orf106 | n.686_694del | RNA (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.*3160G>C | 3'UTR (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99949323; called by muse, mutect2
- GP6 | c.*324G>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100117354; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439157 C>T | 3'Flank (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
